Somatic mutation profile of tumor specimen MMRF_2362_1_BM_CD138pos (aliquot MMRF_2362_1_BM_CD138pos_T1_KHS5U_K13995) from MMRF case MMRF_2362, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.0 years (23,754 days).
Specimen MMRF_2362_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94081950-c83e-4e18-aa11-38c981225aab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2362_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2362_1_PB_Whole_C1_KHS5U_K13994; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9fb6714-8565-4328-ad4c-81e800ab2d66

The open-access MAF lists 94 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 28, Intron 12, Silent 10, 5'UTR 5, RNA 2, Splice Region 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3098T>C p.I1033T (on ENST00000272895 / NM_173076.3; = p.I715T on NM_015657.3) | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754684869; called by muse, mutect2, varscan2
- GRXCR1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780011998, COSV67671645; called by muse, mutect2, varscan2
- IGHJ3 | c.13A>C p.I5L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | PolyPhen benign (0.003); catalogued as rs190698203; called by muse, varscan2
- IGHV2-70 | c.283T>G p.S95A | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs568191048; called by muse, varscan2
- IGHV2-70 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs188243654; called by muse, varscan2
- IGKV1D-8 | c.155G>C p.S52T | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs377343591; called by muse, varscan2
- NPY2R | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755399771, COSV61527694; called by muse, mutect2, varscan2
- PCSK2 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99360392; called by muse, mutect2, varscan2
- PREX1 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 137/318 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs1172591295, COSV64248827; called by muse, varscan2
- PTRH1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 98/291 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs201042035; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1074A>T p.L358F | Missense Mutation (SNP) | VAF 111/243 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH18 | c.2366C>A p.T789K | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CFAP221 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- COL12A1 | c.9012T>A p.G3004= | Splice Region (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- DIS3 | c.2352T>A p.D784E | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIS3 | c.2291A>C p.H764P | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRD5 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- GRIA2 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 112/301 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- IGLL5 | c.26del p.G9Vfs*100 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | called by pindel, varscan2
- NFKBID | c.64G>T p.V22F (on ENST00000396901; = p.V174F on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NIBAN1 | c.2531G>C p.C844S | Missense Mutation (SNP) | VAF 191/569 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PAPPA2 | c.3515G>A p.R1172K | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHA13 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PDZRN4 | c.1992T>G p.H664Q (on ENST00000402685 / NM_001164595.2; = p.H406Q on NM_013377.4) | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PURG | c.899T>C p.I300T | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- RDH8 | c.248C>T p.A83V (on ENST00000651512; = p.A63V on NM_015725.4) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by mutect2, varscan2
- RHOQ | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SGO2 | c.3338C>G p.A1113G | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- SOX14 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 104/305 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- TMTC2 | c.2453A>G p.N818S | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM29 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- UTP20 | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- WDR64 | c.257C>A p.A86E | Missense Mutation (SNP) | VAF 16/520 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.17); called by muse, mutect2
- WNT8B | c.939C>G p.F313L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZYG11B | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACOT11 | c.642G>A p.P214= | Silent (SNP) | VAF 55/121 reads (45%) | catalogued as rs542118385, COSV59352485; called by muse, mutect2, varscan2
- ARID1B | c.1320C>T p.Y440= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs1307271255; called by muse, mutect2, varscan2
- ARMC4 | c.1011T>A p.A337= | Silent (SNP) | VAF 39/135 reads (29%) | called by muse, mutect2, varscan2
- ATP8B1 | c.2337C>T p.Y779= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs764863689; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GSTO2 | c.549G>A p.E183= | Silent (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.174C>A p.I58= | Silent (SNP) | VAF 49/98 reads (50%) | catalogued as rs371385744; called by muse, varscan2
- MLIP | c.1059A>G p.E353= | Silent (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- NR4A1 | c.78G>A p.L26= | Silent (SNP) | VAF 154/366 reads (42%) | called by muse, mutect2
- PTPRC | c.2320C>A p.R774= | Silent (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- ZXDB | c.1734C>T p.L578= | Silent (SNP) | VAF 116/149 reads (78%) | catalogued as COSV100885945; called by muse, mutect2, varscan2
- AC139491.1 | n.874G>T | RNA (SNP) | VAF 160/510 reads (31%) | called by muse, mutect2, varscan2
- ACAD8 | c.1195+777G>T | Intron (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- ANAPC5 | c.-21_-1del | 5'UTR (DEL) | VAF 63/223 reads (28%) | called by mutect2, pindel, varscan2
- AQP4 | c.*3763G>T | 3'UTR (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP40 | c.*754A>C | 3'UTR (SNP) | VAF 28/58 reads (48%) | catalogued as rs1478408731; called by muse, mutect2
- BCL7A | chr12:122021688 C>A | 5'Flank (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
- BSG | c.416-243G>A | Intron (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- C16orf70 | c.661+217G>A | Intron (SNP) | VAF 30/54 reads (56%) | catalogued as rs774006059; called by muse, mutect2, varscan2
- C20orf202 | c.-4G>T | 5'UTR (SNP) | VAF 58/180 reads (32%) | called by muse, mutect2, varscan2
- CCDC6 | c.*4062T>C | 3'UTR (SNP) | VAF 136/353 reads (39%) | called by muse, mutect2, varscan2
- CDH6 | c.*5719A>G | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- CTBP2 | c.*2197G>A | 3'UTR (SNP) | VAF 11/26 reads (42%) | catalogued as rs1278898432; called by muse, mutect2, varscan2
- CYP17A1 | c.970-9G>A | Intron (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- DPY19L4 | c.*3564G>C | 3'UTR (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- GADL1 | c.1250+1476G>T | Intron (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- GSG1 | c.*1356A>G | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by mutect2, varscan2
- IGLL5 | c.-62A>C | 5'UTR (SNP) | VAF 25/54 reads (46%) | catalogued as COSV104440267, COSV73250539; called by muse, varscan2
- JAKMIP2 | c.-370C>T | 5'UTR (SNP) | VAF 40/102 reads (39%) | called by muse, varscan2
- LINC02347 | n.417C>A | RNA (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- MAGOHB | c.264+445C>T | Intron (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- MAP3K21 | c.*1929T>C | 3'UTR (SNP) | VAF 50/87 reads (57%) | catalogued as rs912251564; called by muse, mutect2, varscan2
- MARVELD2 | c.*902G>A | 3'UTR (SNP) | VAF 33/93 reads (35%) | catalogued as rs760221748; called by muse, mutect2, varscan2
- MIB1 | c.1372-12T>A | Intron (SNP) | VAF 10/27 reads (37%) | catalogued as rs772089721, COSV55088334; called by muse, mutect2, varscan2
- MIB1 | c.*3972A>G | 3'UTR (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- MTO1 | c.*8229G>A | 3'UTR (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- MTO1 | c.*8230C>G | 3'UTR (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- NCAM2 | c.*4767T>G | 3'UTR (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- NR2E1 | c.*1326A>T | 3'UTR (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- PARD3B | c.*4065C>G | 3'UTR (SNP) | VAF 58/159 reads (36%) | called by muse, mutect2, varscan2
- PIGP | c.*13C>T | 3'UTR (SNP) | VAF 18/287 reads (6%) | catalogued as rs751402808; called by muse, mutect2
- POC1B | c.*1151G>C | 3'UTR (SNP) | VAF 44/101 reads (44%) | called by muse, mutect2, varscan2
- PPP1R10 | c.*893T>A | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- RAB6C | c.*806dup | 3'UTR (INS) | VAF 60/138 reads (43%) | catalogued as rs773116651; called by mutect2, varscan2
- RAP2B | c.*419C>T | 3'UTR (SNP) | VAF 8/12 reads (67%) | catalogued as rs144462183; called by muse, varscan2
- RBM33 | c.*2998T>C | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- RUNX2 | c.*831A>T | 3'UTR (SNP) | VAF 42/127 reads (33%) | catalogued as rs1248873981; called by muse, mutect2, varscan2
- SNX21 | c.*898G>C | 3'UTR (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- STOML2 | c.805-40G>A | Intron (SNP) | VAF 69/152 reads (45%) | catalogued as rs763463174; called by muse, mutect2, varscan2
- STX17 | c.190-5336G>T | Intron (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- TDG | c.*149C>T | 3'UTR (SNP) | VAF 80/452 reads (18%) | catalogued as rs1392591828; called by muse, mutect2, varscan2
- TECRL | c.*1335A>G | 3'UTR (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- TMEM184C | c.*816T>G | 3'UTR (SNP) | VAF 37/64 reads (58%) | called by muse, mutect2, varscan2
- TTBK1 | c.*259G>A | 3'UTR (SNP) | VAF 73/164 reads (45%) | called by muse, mutect2, varscan2
- USP11 | c.976-104C>G | Intron (SNP) | VAF 19/22 reads (86%) | called by muse, mutect2, varscan2
- VPS13A | c.-116G>A | 5'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- VWA3B | c.*386T>C | 3'UTR (SNP) | VAF 40/114 reads (35%) | catalogued as rs534626033; called by muse, mutect2, varscan2
- WIPF1 | c.1129+96T>C | Intron (SNP) | VAF 94/240 reads (39%) | called by muse, mutect2, varscan2
- ZNF140 | c.10-178A>G | Intron (SNP) | VAF 5/62 reads (8%) | catalogued as rs1280469600; called by muse, mutect2
